Somatic mutation profile of tumor specimen MMRF_2072_1_BM_CD138pos (aliquot MMRF_2072_1_BM_CD138pos_T1_KHS5U_L08079) from MMRF case MMRF_2072, project MMRF-COMMPASS (Multiple Myeloma CoMMpass Study). Sex at birth: female; Vital status: Alive; Primary diagnosis: Multiple myeloma; Tissue or organ of origin: Bone marrow; Age at diagnosis: 73.3 years (26,758 days).
Specimen MMRF_2072_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 209416ea-e66c-49ee-b9bb-3a5541cac852.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MMRF_2072_1_PB_Whole (Blood Derived Normal), aliquot MMRF_2072_1_PB_Whole_C2_KHS5U_L08080; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/7b219147-f7cd-44df-abbc-421062fe4949

The open-access MAF lists 226 somatic variants for this specimen: 87 protein-altering or splice-affecting, 34 silent, 105 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 72, 3'UTR 68, Silent 34, Intron 21, Nonsense Mutation 9, 5'UTR 9, 3'Flank 4, Frame Shift Del 3, Translation Start Site 2, RNA 2, 5'Flank 1, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ERCC6 | c.229C>T p.R77* | Nonsense Mutation (SNP) | VAF 65/223 reads (29%) | catalogued as rs121917903, CM046039; ClinVar: pathogenic; called by muse, mutect2, varscan2
- TP53 | c.596G>T p.G199V | Missense Mutation (SNP) | VAF 8/131 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1555525857, COSV52661319, COSV52679535, COSV53326529; ClinVar: likely pathogenic; called by muse, mutect2
- ATP6V0A1 | c.16C>T p.R6W | Missense Mutation (SNP) | VAF 24/67 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.815); catalogued as rs1243690493, COSV52871861; called by muse, mutect2, varscan2
- ATRX | c.3121G>A p.D1041N | Missense Mutation (SNP) | VAF 7/50 reads (14%) | SIFT tolerated, low confidence (0.17); PolyPhen benign (0.031); catalogued as rs1386901513; called by muse, mutect2, varscan2
- AVPR1B | c.874G>A p.A292T | Missense Mutation (SNP) | VAF 12/98 reads (12%) | SIFT deleterious (0.05); PolyPhen benign (0.273); catalogued as rs782178334; called by mutect2, varscan2
- BMP5 | c.847G>A p.V283I | Missense Mutation (SNP) | VAF 15/48 reads (31%) | SIFT tolerated (0.06); PolyPhen benign (0.013); catalogued as rs748147968; called by muse, mutect2, varscan2
- CACNB2 | c.1421C>G p.P474R (on ENST00000324631 / NM_201596.3; = p.P419R on NM_000724.4) | Missense Mutation (SNP) | VAF 44/156 reads (28%) | SIFT deleterious (0); PolyPhen benign (0.221); catalogued as rs759185685; called by muse, mutect2, varscan2
- CASP14 | c.512C>T p.T171M | Missense Mutation (SNP) | VAF 58/126 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs141847530; called by muse, mutect2, varscan2
- CBL | c.1802C>G p.S601C | Missense Mutation (SNP) | VAF 16/214 reads (7%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.219); catalogued as rs775302733; called by muse, mutect2
- CREBRF | c.682C>T p.H228Y | Missense Mutation (SNP) | VAF 77/368 reads (21%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.025); catalogued as COSV51636395; called by muse, mutect2, varscan2
- CRISP3 | c.345C>G p.H115Q (on ENST00000371159 / NM_001368123.1; = p.H97Q on NM_006061.4) | Missense Mutation (SNP) | VAF 20/132 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs1432316918, COSV53819622; called by mutect2, varscan2
- CRY2 | c.736C>T p.R246W | Missense Mutation (SNP) | VAF 127/177 reads (72%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.93); catalogued as rs751642703, COSV69889165; called by muse, mutect2, varscan2
- FAM155A | c.1232G>T p.R411I | Missense Mutation (SNP) | VAF 30/36 reads (83%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV65562322; called by muse, mutect2, varscan2
- FAM83F | c.1007C>T p.P336L | Missense Mutation (SNP) | VAF 45/95 reads (47%) | SIFT deleterious (0); PolyPhen benign (0.401); catalogued as rs753758914; called by muse, mutect2, varscan2
- HNRNPM | c.898G>T p.G300C | Missense Mutation (SNP) | VAF 21/91 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); catalogued as COSV100335123; called by muse, mutect2, varscan2
- IGHV2-70 | c.223G>A p.D75N | Missense Mutation (SNP) | VAF 37/106 reads (35%) | SIFT tolerated (0.32); PolyPhen benign (0); catalogued as rs377473012; called by muse, varscan2
- IGHV2-70 | c.167G>T p.S56I | Missense Mutation (SNP) | VAF 50/108 reads (46%) | SIFT deleterious (0.04); PolyPhen benign (0.352); catalogued as rs370560636; called by muse, varscan2
- IGLV5-45 | c.143A>T p.N48I | Missense Mutation (SNP) | VAF 48/122 reads (39%) | SIFT deleterious (0.04); PolyPhen benign (0.015); catalogued as rs202076025; called by muse, varscan2
- IRS1 | c.691A>T p.T231S | Missense Mutation (SNP) | VAF 16/181 reads (9%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as COSV59341783; called by muse, mutect2
- KRBA1 | c.2831C>T p.A944V | Missense Mutation (SNP) | VAF 12/95 reads (13%) | SIFT tolerated (1); PolyPhen benign (0.007); catalogued as rs201008343, COSV55440878; called by muse, mutect2, varscan2
- LRRC14 | c.1121_1124del p.E374Vfs*15 | Frame Shift Del (DEL) | VAF 13/123 reads (11%) | catalogued as rs760735477; called by mutect2, pindel
- MOGAT2 | c.193C>T p.R65W | Missense Mutation (SNP) | VAF 69/454 reads (15%) | SIFT tolerated (0.16); PolyPhen benign (0.015); catalogued as rs773970049, COSV52219517; called by muse, mutect2, varscan2
- MYO19 | c.670C>T p.R224* | Nonsense Mutation (SNP) | VAF 20/98 reads (20%) | catalogued as rs766865716; called by muse, mutect2, varscan2
- OLFML2A | c.1711C>T p.R571W | Missense Mutation (SNP) | VAF 47/280 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as rs369965570, COSV56585775, COSV99992653; called by muse, mutect2, varscan2
- PCDHA8 | c.1985C>T p.T662M | Missense Mutation (SNP) | VAF 40/153 reads (26%) | SIFT deleterious, low confidence (0.03); PolyPhen probably damaging (0.946); catalogued as rs1393236321, COSV65324971; called by muse, mutect2, varscan2
- PCDHAC2 | c.3G>A p.M1? | Translation Start Site (SNP) | VAF 12/33 reads (36%) | SIFT deleterious, low confidence (0); PolyPhen benign (0); catalogued as COSV53838986; called by muse, mutect2, varscan2
- PHACTR2 | c.641G>A p.R214Q | Missense Mutation (SNP) | VAF 25/105 reads (24%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.616); catalogued as rs765018404, COSV59855756; called by muse, mutect2, varscan2
- PILRA | c.398G>A p.S133N | Missense Mutation (SNP) | VAF 108/180 reads (60%) | SIFT tolerated (0.6); PolyPhen benign (0.001); catalogued as rs556203759; called by muse, varscan2
- RADIL | c.142G>A p.A48T | Missense Mutation (SNP) | VAF 36/111 reads (32%) | SIFT tolerated (0.23); PolyPhen benign (0.003); catalogued as rs200059500; called by muse, mutect2, varscan2
- RP1L1 | c.2687G>A p.G896D | Missense Mutation (SNP) | VAF 20/33 reads (61%) | SIFT tolerated (0.31); PolyPhen benign (0.057); catalogued as rs774135283; called by muse, mutect2, varscan2
- SIGLEC8 | c.964G>T p.D322Y | Missense Mutation (SNP) | VAF 23/134 reads (17%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.949); catalogued as COSV58471967; called by muse, mutect2, varscan2
- SLC35D3 | c.859G>A p.V287M | Missense Mutation (SNP) | VAF 14/179 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as rs746388387, COSV59378400; called by muse, mutect2
- TBKBP1 | c.1099G>A p.V367I | Missense Mutation (SNP) | VAF 5/15 reads (33%) | SIFT tolerated (0.63); PolyPhen benign (0.007); catalogued as rs1392898839; called by muse, mutect2, varscan2
- TDRD12 | c.3105C>G p.I1035M (on ENST00000444215; = p.I1040M on NM_001366102.1) | Missense Mutation (SNP) | VAF 24/62 reads (39%) | SIFT tolerated (0.13); PolyPhen benign (0.003); catalogued as COSV71445217; called by muse, mutect2, varscan2
- TNFRSF11B | c.412C>T p.R138* | Nonsense Mutation (SNP) | VAF 34/89 reads (38%) | catalogued as rs1201638030, COSV99816513; called by muse, mutect2, varscan2
- TRPC3 | c.2539C>T p.R847C (on ENST00000379645 / NM_001366479.2; = p.R774C on NM_003305.2) | Missense Mutation (SNP) | VAF 38/102 reads (37%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.836); catalogued as rs138232580, COSV53379506; called by muse, mutect2, varscan2
- UGGT2 | c.2829T>A p.D943E | Missense Mutation (SNP) | VAF 13/13 reads (100%) | SIFT tolerated (0.58); PolyPhen benign (0.023); catalogued as COSV100948915; called by muse, mutect2, varscan2
- UNC5A | c.715G>A p.V239I | Missense Mutation (SNP) | VAF 7/96 reads (7%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.999); catalogued as rs1418893349; called by muse, mutect2
- VEGFD | c.686A>G p.D229G | Missense Mutation (SNP) | VAF 6/66 reads (9%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV52911387; called by muse, mutect2
- AC144573.1 | c.820C>G p.L274V | Missense Mutation (SNP) | VAF 12/174 reads (7%) | SIFT deleterious, low confidence (0); called by muse, mutect2
- ADCY9 | c.2155A>G p.N719D | Missense Mutation (SNP) | VAF 91/93 reads (98%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.906); called by muse, mutect2, varscan2
- ASTN2 | c.895G>A p.E299K | Missense Mutation (SNP) | VAF 31/299 reads (10%) | SIFT tolerated, low confidence (0.21); PolyPhen benign (0.021); called by muse, mutect2
- CD24 | c.98C>A p.T33N | Missense Mutation (SNP) | VAF 13/42 reads (31%) | SIFT tolerated (0.08); PolyPhen benign (0.203); called by muse, mutect2, varscan2
- CFAP47 | c.4298A>C p.Q1433P | Missense Mutation (SNP) | VAF 41/67 reads (61%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.898); called by muse, mutect2, varscan2
- CRPPA | c.385T>C p.S129P | Missense Mutation (SNP) | VAF 23/149 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- CSPG4 | c.2299C>T p.Q767* | Nonsense Mutation (SNP) | VAF 5/78 reads (6%) | called by muse, mutect2
- CYP19A1 | c.831C>A p.D277E | Missense Mutation (SNP) | VAF 26/446 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); called by muse, mutect2
- DDX60L | c.2564A>C p.H855P | Missense Mutation (SNP) | VAF 5/16 reads (31%) | SIFT deleterious (0.01); PolyPhen benign (0.281); called by muse, mutect2, varscan2
- FRAS1 | c.10899G>T p.L3633F | Missense Mutation (SNP) | VAF 17/67 reads (25%) | SIFT deleterious (0); PolyPhen benign (0); called by muse, mutect2, varscan2
- HEATR1 | c.5045G>A p.G1682D | Missense Mutation (SNP) | VAF 19/210 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2
- HERC2 | c.12684G>C p.R4228S | Missense Mutation (SNP) | VAF 73/154 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- HHIPL2 | c.1921G>T p.E641* | Nonsense Mutation (SNP) | VAF 49/151 reads (32%) | called by muse, mutect2, varscan2
- KRT1 | c.749C>T p.S250F | Missense Mutation (SNP) | VAF 29/69 reads (42%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.978); called by muse, mutect2, varscan2
- LRRTM4 | c.905C>A p.S302* | Nonsense Mutation (SNP) | VAF 13/108 reads (12%) | called by mutect2, varscan2
- LY75 | c.871T>C p.W291R | Missense Mutation (SNP) | VAF 12/162 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- MKRN2 | c.61C>T p.Q21* | Nonsense Mutation (SNP) | VAF 6/102 reads (6%) | called by muse, mutect2
- NR3C2 | c.405G>T p.Q135H | Missense Mutation (SNP) | VAF 96/174 reads (55%) | SIFT deleterious, low confidence (0.03); PolyPhen possibly damaging (0.854); called by muse, mutect2, varscan2
- OR1N1 | c.124C>A p.L42I | Missense Mutation (SNP) | VAF 70/146 reads (48%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- OSBPL8 | c.326G>A p.S109N | Missense Mutation (SNP) | VAF 191/204 reads (94%) | SIFT tolerated (0.23); PolyPhen benign (0); called by muse, mutect2, varscan2
- PCDH10 | c.1184G>A p.C395Y | Missense Mutation (SNP) | VAF 45/127 reads (35%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.915); called by muse, mutect2, varscan2
- PEX5L | c.1068C>A p.D356E | Missense Mutation (SNP) | VAF 7/31 reads (23%) | SIFT tolerated (0.21); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- PGAP1 | c.1A>G p.M1? | Translation Start Site (SNP) | VAF 52/163 reads (32%) | SIFT tolerated, low confidence (0.5); PolyPhen benign (0.067); called by muse, mutect2, varscan2
- POLE | c.1226G>A p.R409K | Missense Mutation (SNP) | VAF 4/76 reads (5%) | SIFT tolerated (0.94); PolyPhen benign (0.036); called by muse, mutect2
- PTGFRN | c.368G>A p.S123N | Missense Mutation (SNP) | VAF 17/147 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- RABGGTA | c.1111T>A p.C371S | Missense Mutation (SNP) | VAF 19/47 reads (40%) | SIFT deleterious (0); PolyPhen benign (0.327); called by muse, mutect2, varscan2
- RBM22 | c.710del p.G237Vfs*3 | Frame Shift Del (DEL) | VAF 10/62 reads (16%) | called by mutect2, pindel, varscan2
- REEP1 | c.24G>T p.R8S | Missense Mutation (SNP) | VAF 12/30 reads (40%) | SIFT deleterious (0.01); PolyPhen benign (0.196); called by muse, mutect2, varscan2
- SEC14L6 | c.426G>C p.L142= | Splice Region (SNP) | VAF 22/78 reads (28%) | called by muse, mutect2
- SENP6 | c.1499G>T p.R500L | Missense Mutation (SNP) | VAF 16/126 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.948); called by muse, mutect2, varscan2
- SHISA7 | c.1535C>T p.T512M | Missense Mutation (SNP) | VAF 8/46 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.958); called by muse, mutect2, varscan2
- SLITRK3 | c.1358T>G p.I453S | Missense Mutation (SNP) | VAF 26/176 reads (15%) | SIFT tolerated (0.77); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- SNTA1 | c.1423A>T p.I475F | Missense Mutation (SNP) | VAF 54/124 reads (44%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.834); called by muse, varscan2
- SORL1 | c.2152G>C p.V718L | Missense Mutation (SNP) | VAF 17/118 reads (14%) | SIFT tolerated (0.16); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- SPATA2 | c.199T>C p.Y67H | Missense Mutation (SNP) | VAF 5/59 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- SPATS2L | c.1491G>T p.K497N | Missense Mutation (SNP) | VAF 6/62 reads (10%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.343); called by muse, mutect2
- TARS2 | c.2062A>G p.N688D | Missense Mutation (SNP) | VAF 38/129 reads (29%) | SIFT tolerated (0.28); PolyPhen benign (0.42); called by muse, mutect2, varscan2
- TEX11 | c.1398T>A p.C466* (on ENST00000344304; = p.C451* on NM_031276.3) | Nonsense Mutation (SNP) | VAF 6/134 reads (4%) | called by muse, mutect2
- TGDS | c.388C>G p.H130D | Missense Mutation (SNP) | VAF 30/41 reads (73%) | SIFT tolerated (0.06); PolyPhen benign (0.136); called by muse, varscan2
- TJP1 | c.578G>C p.R193P | Missense Mutation (SNP) | VAF 20/190 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- TMEM253 | c.348G>A p.M116I | Missense Mutation (SNP) | VAF 7/82 reads (9%) | SIFT tolerated (0.58); PolyPhen benign (0); called by muse, mutect2
- TRAP1 | c.703G>C p.G235R | Missense Mutation (SNP) | VAF 5/68 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- TRPM1 | c.773C>T p.P258L | Missense Mutation (SNP) | VAF 13/237 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2
- TTN | c.90979A>G p.T30327A (on ENST00000591111; = p.T22903A on NM_003319.4) | Missense Mutation (SNP) | VAF 21/306 reads (7%) | PolyPhen benign (0); called by muse, mutect2
- UNC80 | c.9202A>T p.R3068* | Nonsense Mutation (SNP) | VAF 6/84 reads (7%) | called by muse, mutect2
- WDR1 | c.151G>C p.A51P | Missense Mutation (SNP) | VAF 13/48 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- ZNF488 | c.12del p.W4Cfs*12 | Frame Shift Del (DEL) | VAF 49/368 reads (13%) | called by mutect2, pindel, varscan2
- ZNF544 | c.2079T>G p.C693W | Missense Mutation (SNP) | VAF 36/95 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- A1CF | c.795T>A p.I265= | Silent (SNP) | VAF 37/213 reads (17%) | catalogued as COSV50978884; called by muse, mutect2, varscan2
- ABCD1 | c.1239T>A p.A413= | Silent (SNP) | VAF 19/170 reads (11%) | called by muse, mutect2, varscan2
- ASB6 | c.408C>T p.H136= | Silent (SNP) | VAF 10/68 reads (15%) | catalogued as rs757992602; called by muse, mutect2, varscan2
- C1QTNF2 | c.654G>A p.L218= (on ENST00000393975; = p.L173= on NM_031908.6 and 1 other RefSeq transcript) | Silent (SNP) | VAF 11/313 reads (4%) | called by muse, mutect2
- CD22 | c.6T>C p.H2= | Silent (SNP) | VAF 44/187 reads (24%) | catalogued as rs1208977889; called by muse, mutect2, varscan2
- COBL | c.3441G>A p.E1147= | Silent (SNP) | VAF 18/82 reads (22%) | called by muse, mutect2, varscan2
- DUXA | c.600A>G p.G200= | Silent (SNP) | VAF 116/222 reads (52%) | called by muse, mutect2
- F2RL2 | c.876C>T p.Y292= | Silent (SNP) | VAF 14/62 reads (23%) | catalogued as rs201640652, COSV56969942; called by muse, mutect2, varscan2
- FANCM | c.3438T>C p.D1146= | Silent (SNP) | VAF 14/154 reads (9%) | called by muse, mutect2
- GRM6 | c.1857G>C p.S619= | Silent (SNP) | VAF 13/119 reads (11%) | catalogued as rs140658210, COSV51442043, COSV99179538; called by muse, mutect2, varscan2
- IGHV2-70D | c.168C>T p.S56= | Silent (SNP) | VAF 38/87 reads (44%) | catalogued as rs1233195687; called by muse, varscan2
- KCNK1 | c.42G>T p.V14= | Silent (SNP) | VAF 13/32 reads (41%) | catalogued as COSV100785895; called by mutect2, varscan2
- KLHL20 | c.1698A>G p.T566= | Silent (SNP) | VAF 50/174 reads (29%) | catalogued as rs756885432; called by muse, mutect2, varscan2
- LAMA2 | c.4803G>A p.P1601= | Silent (SNP) | VAF 9/48 reads (19%) | catalogued as rs766521929, COSV101370745; called by muse, mutect2, varscan2
- LMTK3 | c.537C>T p.I179= | Silent (SNP) | VAF 65/316 reads (21%) | called by muse, mutect2, varscan2
- LRFN3 | c.1200G>A p.P400= | Silent (SNP) | VAF 41/171 reads (24%) | catalogued as rs757539152; called by muse, mutect2, varscan2
- MROH7 | c.468C>G p.L156= | Silent (SNP) | VAF 19/133 reads (14%) | called by muse, mutect2, varscan2
- NAALADL1 | c.804C>T p.F268= | Silent (SNP) | VAF 14/226 reads (6%) | called by muse, mutect2
- NOL9 | c.1986T>C p.Y662= | Silent (SNP) | VAF 14/242 reads (6%) | called by muse, mutect2
- NRARP | c.300G>A p.V100= | Silent (SNP) | VAF 24/260 reads (9%) | called by muse, mutect2
- OR7D2 | c.900C>T p.A300= | Silent (SNP) | VAF 28/194 reads (14%) | called by muse, mutect2, varscan2
- RBFOX3 | c.48C>T p.N16= | Silent (SNP) | VAF 6/37 reads (16%) | catalogued as rs561710608; called by muse, mutect2, varscan2
- SIPA1L2 | c.3189C>T p.N1063= | Silent (SNP) | VAF 8/42 reads (19%) | catalogued as rs764448843; called by muse, mutect2
- SLITRK1 | c.972G>A p.A324= | Silent (SNP) | VAF 5/31 reads (16%) | catalogued as rs1467266519, COSV65674393, COSV65676911; called by muse, mutect2, varscan2
- SNTA1 | c.1422G>A p.E474= | Silent (SNP) | VAF 53/125 reads (42%) | called by muse, varscan2
- STARD13 | c.627C>A p.R209= (on ENST00000336934 / NM_001243476.3; = p.R91= on NM_052851.3) | Silent (SNP) | VAF 3/38 reads (8%) | called by muse, mutect2
- SYNPO | c.1101C>A p.L367= (on ENST00000394243 / NM_001166208.2; = p.L123= on NM_007286.6) | Silent (SNP) | VAF 83/415 reads (20%) | catalogued as COSV56937900; called by muse, mutect2, varscan2
- TCTE1 | c.693C>T p.G231= | Silent (SNP) | VAF 10/138 reads (7%) | catalogued as rs1024748008; called by muse, mutect2
- TEX15 | c.1155A>G p.P385= (on ENST00000256246; = p.P768= on NM_001350162.2) | Silent (SNP) | VAF 19/50 reads (38%) | called by muse, mutect2, varscan2
- TSKU | c.549G>A p.A183= | Silent (SNP) | VAF 26/413 reads (6%) | catalogued as rs747455352, COSV60752389; called by muse, mutect2
- TSPAN6 | c.714A>T p.T238= | Silent (SNP) | VAF 21/207 reads (10%) | called by muse, mutect2
- TTN | c.17961T>A p.V5987= (on ENST00000591111; = p.V5060= on NM_133378.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 14/216 reads (6%) | called by muse, mutect2
- WASF3 | c.1239T>C p.S413= | Silent (SNP) | VAF 24/91 reads (26%) | called by muse, mutect2, varscan2
- ZBED1 | c.375G>A p.E125= | Silent (SNP) | VAF 4/22 reads (18%) | catalogued as rs1264011897; called by mutect2, varscan2
- AC092818.1 | n.464T>A | RNA (SNP) | VAF 28/57 reads (49%) | catalogued as rs1166174455; called by muse, mutect2, varscan2
- ACSL4 | c.-15A>T | 5'UTR (SNP) | VAF 11/57 reads (19%) | called by muse, mutect2, varscan2
- ADGRF5 | c.*610C>T | 3'UTR (SNP) | VAF 62/226 reads (27%) | called by muse, mutect2, varscan2
- ADGRL2 | c.*832T>G | 3'UTR (SNP) | VAF 42/59 reads (71%) | called by muse, mutect2, varscan2
- AKTIP | c.*661A>C | 3'UTR (SNP) | VAF 12/150 reads (8%) | called by muse, mutect2
- ANK2 | c.11611-488G>A | Intron (SNP) | VAF 7/51 reads (14%) | called by muse, mutect2, varscan2
- APBB1 | c.722-109C>T | Intron (SNP) | VAF 16/26 reads (62%) | called by muse, mutect2
- BCL6 | c.1977+16G>T | Intron (SNP) | VAF 35/54 reads (65%) | called by muse, mutect2, varscan2
- BDNF | c.*1256C>T | 3'UTR (SNP) | VAF 61/186 reads (33%) | called by muse, mutect2, varscan2
- BEST4 | c.*353C>T | 3'UTR (SNP) | VAF 22/70 reads (31%) | called by muse, mutect2, varscan2
- BRI3BP | c.*5381G>A | 3'UTR (SNP) | VAF 17/55 reads (31%) | called by muse, mutect2, varscan2
- C10orf53 | c.*606G>A | 3'UTR (SNP) | VAF 28/152 reads (18%) | called by muse, mutect2, varscan2
- C21orf58 | c.-485C>T | 5'UTR (SNP) | VAF 9/144 reads (6%) | catalogued as rs1163675355; called by muse, mutect2
- CAB39 | c.*930T>G | 3'UTR (SNP) | VAF 68/92 reads (74%) | called by muse, mutect2, varscan2
- CADM1 | c.*1876C>G | 3'UTR (SNP) | VAF 16/123 reads (13%) | called by muse, mutect2, varscan2
- CCNQ | c.*433C>A | 3'UTR (SNP) | VAF 10/130 reads (8%) | called by muse, mutect2
- CDC42BPA | c.-354G>A | 5'UTR (SNP) | VAF 9/22 reads (41%) | called by muse, mutect2, varscan2
- CDKN1B | c.*559G>A | 3'UTR (SNP) | VAF 7/9 reads (78%) | called by muse, mutect2, varscan2
- CDSN | c.*692T>C | 3'UTR (SNP) | VAF 67/99 reads (68%) | called by muse, mutect2, varscan2
- CELSR1 | c.*750C>T | 3'UTR (SNP) | VAF 8/155 reads (5%) | called by muse, mutect2
- CEP170 | c.*1427A>G | 3'UTR (SNP) | VAF 27/91 reads (30%) | called by muse, varscan2
- CEP170 | c.*1348T>C | 3'UTR (SNP) | VAF 44/157 reads (28%) | called by muse, varscan2
- CEP170 | c.*1004T>A | 3'UTR (SNP) | VAF 119/381 reads (31%) | called by muse, mutect2, varscan2
- CEP170 | c.*229T>C | 3'UTR (SNP) | VAF 97/384 reads (25%) | called by muse, mutect2, varscan2
- CLEC4C | c.*155A>G | 3'UTR (SNP) | VAF 7/21 reads (33%) | called by muse, mutect2, varscan2
- CNR2 | c.*3591C>T | 3'UTR (SNP) | VAF 3/15 reads (20%) | called by muse, mutect2
- CNR2 | c.*14C>T | 3'UTR (SNP) | VAF 108/192 reads (56%) | called by muse, mutect2
- COLGALT2 | c.1137-372C>A | Intron (SNP) | VAF 17/150 reads (11%) | called by muse, mutect2, varscan2
- CSMD3 | c.178+59902C>A | Intron (SNP) | VAF 22/146 reads (15%) | catalogued as COSV52299789; called by muse, mutect2, varscan2
- CYP2A7 | c.*2C>A | 3'UTR (SNP) | VAF 7/98 reads (7%) | catalogued as COSV99393988; called by muse, mutect2
- DACT1 | chr14:58648059 G>T | 3'Flank (SNP) | VAF 8/31 reads (26%) | called by mutect2, varscan2
- DAPK2 | c.660-36C>A | Intron (SNP) | VAF 15/72 reads (21%) | called by muse, mutect2, varscan2
- DOCK2 | c.*383A>G | 3'UTR (SNP) | VAF 14/72 reads (19%) | called by muse, mutect2, varscan2
- DZIP1 | c.2028-42G>A | Intron (SNP) | VAF 13/21 reads (62%) | catalogued as rs765997376, COSV61263687; called by muse, mutect2, varscan2
- EDA | c.*3619T>G | 3'UTR (SNP) | VAF 12/50 reads (24%) | called by muse, mutect2, varscan2
- EIF3A | c.*1857G>T | 3'UTR (SNP) | VAF 8/65 reads (12%) | called by muse, mutect2, varscan2
- ELOVL6 | c.*3880A>G | 3'UTR (SNP) | VAF 9/58 reads (16%) | called by muse, mutect2, varscan2
- EPHA5 | c.*2581G>A | 3'UTR (SNP) | VAF 9/45 reads (20%) | called by muse, mutect2, varscan2
- ERAP1 | c.*1105T>C | 3'UTR (SNP) | VAF 12/70 reads (17%) | called by muse, mutect2, varscan2
- FBN2 | c.-87A>T | 5'UTR (SNP) | VAF 30/156 reads (19%) | called by muse, mutect2, varscan2
- FSD2 | c.*1950G>A | 3'UTR (SNP) | VAF 6/21 reads (29%) | called by muse, mutect2, varscan2
- GABRA1 | chr5:161897872 A>T | 3'Flank (SNP) | VAF 6/142 reads (4%) | called by muse, mutect2
- GASK1B | c.910+1782G>A | Intron (SNP) | VAF 16/38 reads (42%) | catalogued as rs1008271681; called by muse, mutect2, varscan2
- GATA5 | c.*889A>C | 3'UTR (SNP) | VAF 8/90 reads (9%) | called by muse, mutect2
- GLP2R | c.*838T>C | 3'UTR (SNP) | VAF 34/102 reads (33%) | called by muse, mutect2
- GPAT4 | c.*1677G>A | 3'UTR (SNP) | VAF 65/67 reads (97%) | called by muse, mutect2, varscan2
- GPR151 | c.*774dup | 3'UTR (INS) | VAF 18/196 reads (9%) | catalogued as rs1328300445; called by mutect2, pindel
- GPRC5C | chr17:74450439 G>A | 3'Flank (SNP) | VAF 36/60 reads (60%) | catalogued as rs915951081; called by muse, mutect2, varscan2
- GPX8 | c.*1126T>C | 3'UTR (SNP) | VAF 8/90 reads (9%) | called by muse, mutect2
- HHIPL1 | c.*1707G>A | 3'UTR (SNP) | VAF 23/57 reads (40%) | called by muse, mutect2, varscan2
- HIC2 | c.*3811_*3813del | 3'UTR (DEL) | VAF 7/66 reads (11%) | called by mutect2, pindel, varscan2
- HTR1A | c.*9G>A | 3'UTR (SNP) | VAF 15/175 reads (9%) | catalogued as rs544273487; called by muse, mutect2
- IDS | c.-154_-143del | 5'UTR (DEL) | VAF 58/147 reads (39%) | called by pindel, varscan2*
- IKZF3 | c.*4736C>G | 3'UTR (SNP) | VAF 12/23 reads (52%) | called by muse, mutect2, varscan2
- KCNJ6 | c.-27-112187C>A | Intron (SNP) | VAF 9/90 reads (10%) | called by muse, mutect2, varscan2
- KRTAP5-5 | c.*14G>A | 3'UTR (SNP) | VAF 25/146 reads (17%) | called by muse, mutect2, varscan2
- LMTK2 | c.-116C>A | 5'UTR (SNP) | VAF 6/52 reads (12%) | called by muse, mutect2, varscan2
- LNPK | c.*2318G>A | 3'UTR (SNP) | VAF 18/136 reads (13%) | called by muse, mutect2, varscan2
- LOX | c.*33G>T | 3'UTR (SNP) | VAF 24/338 reads (7%) | called by muse, mutect2
- MMGT1 | c.*2894T>A | 3'UTR (SNP) | VAF 22/62 reads (35%) | called by muse, mutect2, varscan2
- MOCOS | c.*582T>G | 3'UTR (SNP) | VAF 56/91 reads (62%) | called by muse, mutect2, varscan2
- MS4A4E | c.*61A>G | 3'UTR (SNP) | VAF 14/160 reads (9%) | called by muse, mutect2
- NEUROD4 | c.*393G>A | 3'UTR (SNP) | VAF 17/70 reads (24%) | called by muse, mutect2, varscan2
- NHLH2 | c.-9+223A>C | Intron (SNP) | VAF 26/82 reads (32%) | called by muse, mutect2, varscan2
- NOC3L | c.*292C>A | 3'UTR (SNP) | VAF 10/73 reads (14%) | catalogued as rs780012078, COSV64929671; called by muse, mutect2, varscan2
- NPR3 | c.-206_-205insCTTTT | 5'UTR (INS) | VAF 14/27 reads (52%) | catalogued as rs1554012335; called by mutect2, varscan2
- PARD3B | c.*3500G>A | 3'UTR (SNP) | VAF 16/109 reads (15%) | called by muse, mutect2, varscan2
- PCBP1 | c.-87G>A | 5'UTR (SNP) | VAF 6/76 reads (8%) | catalogued as rs1169892415; called by muse, mutect2
- PCDH19 | c.*681A>G | 3'UTR (SNP) | VAF 12/41 reads (29%) | called by muse, mutect2, varscan2
- PCDHA10 | c.2388+4759C>T | Intron (SNP) | VAF 21/124 reads (17%) | catalogued as rs782227810, COSV56481173; called by muse, mutect2, varscan2
- PDE7B | c.*5C>T | 3'UTR (SNP) | VAF 5/39 reads (13%) | catalogued as COSV100368057; called by muse, mutect2, varscan2
- PDP1 | c.-45+756C>T | Intron (SNP) | VAF 43/89 reads (48%) | called by muse, mutect2, varscan2
- PIK3R1 | c.*795T>A | 3'UTR (SNP) | VAF 7/68 reads (10%) | called by muse, mutect2, varscan2
- PLEKHG1 | c.*2170A>T | 3'UTR (SNP) | VAF 16/83 reads (19%) | called by muse, mutect2, varscan2
- PLXNA2 | c.*2032C>T | 3'UTR (SNP) | VAF 13/94 reads (14%) | catalogued as rs1299769667; called by muse, mutect2, varscan2
- PPP1R12B | c.*2508C>A | 3'UTR (SNP) | VAF 6/100 reads (6%) | called by muse, mutect2
- PRPH | chr12:49293861 T>G | 5'Flank (SNP) | VAF 16/176 reads (9%) | called by muse, mutect2
- RBBP6 | c.1386+46del | Intron (DEL) | VAF 6/62 reads (10%) | called by mutect2, pindel
- REEP3 | c.*2265A>G | 3'UTR (SNP) | VAF 4/44 reads (9%) | called by muse, mutect2
- RPL34-DT | n.248T>C | RNA (SNP) | VAF 6/100 reads (6%) | called by muse, mutect2
- SHANK1 | c.1965-122C>T | Intron (SNP) | VAF 22/244 reads (9%) | catalogued as rs956812087; called by muse, mutect2
- SLC19A1 | c.*1306G>A | 3'UTR (SNP) | VAF 13/74 reads (18%) | called by muse, mutect2, varscan2
- SLC23A2 | c.*2638T>C | 3'UTR (SNP) | VAF 32/54 reads (59%) | called by muse, varscan2
- SLC2A4 | c.*763G>A | 3'UTR (SNP) | VAF 12/26 reads (46%) | called by muse, mutect2, varscan2
- SLC2A8 | c.724-77G>A | Intron (SNP) | VAF 5/74 reads (7%) | called by muse, mutect2
- SNTB2 | c.*5371T>G | 3'UTR (SNP) | VAF 8/68 reads (12%) | called by muse, mutect2, varscan2
- SPATA20 | c.1697+38A>C | Intron (SNP) | VAF 3/13 reads (23%) | called by muse, mutect2
- SRFBP1 | c.*538T>G | 3'UTR (SNP) | VAF 11/46 reads (24%) | called by muse, mutect2, varscan2
- STAP2 | c.*72T>C | 3'UTR (SNP) | VAF 44/98 reads (45%) | called by muse, mutect2, varscan2
- SULF2 | c.*1446G>A | 3'UTR (SNP) | VAF 4/33 reads (12%) | called by muse, mutect2
- SYNE1 | c.2569-753G>A | Intron (SNP) | VAF 12/180 reads (7%) | called by muse, mutect2
- SYTL4 | c.1185-127T>A | Intron (SNP) | VAF 4/56 reads (7%) | called by muse, mutect2
- TAF6L | c.437-34C>T | Intron (SNP) | VAF 89/147 reads (61%) | called by muse, mutect2, varscan2
- TMSB4X | c.-17+122C>G | Intron (SNP) | VAF 50/93 reads (54%) | catalogued as COSV66082183; called by muse, mutect2, varscan2
- TRAK2 | c.*240A>G | 3'UTR (SNP) | VAF 8/136 reads (6%) | called by muse, mutect2
- TTC1 | c.*293G>A | 3'UTR (SNP) | VAF 153/623 reads (25%) | called by muse, mutect2, varscan2
- UBE3C | c.*1569G>A | 3'UTR (SNP) | VAF 6/40 reads (15%) | catalogued as rs924917300; called by mutect2, varscan2
- VNN3 | c.*20C>A | 3'UTR (SNP) | VAF 12/268 reads (4%) | catalogued as rs1249842995; called by muse, mutect2
- WDFY1 | c.*1782T>C | 3'UTR (SNP) | VAF 15/128 reads (12%) | called by muse, mutect2, varscan2
- WHAMMP3 | chr15:22690841 C>G | 3'Flank (SNP) | VAF 17/133 reads (13%) | called by muse, mutect2, varscan2
- XPO5 | c.3067-135C>T | Intron (SNP) | VAF 4/14 reads (29%) | called by muse, mutect2
- YIPF6 | c.*1976C>T | 3'UTR (SNP) | VAF 6/44 reads (14%) | called by muse, mutect2, varscan2
- ZBTB40 | c.*3407G>A | 3'UTR (SNP) | VAF 6/80 reads (8%) | called by muse, mutect2
- ZEB2 | c.*871C>T | 3'UTR (SNP) | VAF 6/28 reads (21%) | catalogued as rs1376382997; called by muse, mutect2, varscan2
- ZNF675 | c.-66G>T | 5'UTR (SNP) | VAF 79/177 reads (45%) | catalogued as COSV100704951; called by muse, mutect2, varscan2
